Gene-level copy-number profile of tumor specimen C3N-00709-01 from CPTAC case C3N-00709, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen C3N-00709-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f7ca092e-aa41-4fbe-98c6-937d853eda5f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00709-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/175c99f9-c955-4f7d-a8c4-605d1e7f5f7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 17,660; copy number 2: 35,172; copy number 3: 4,720; copy number 4: 590; copy number 5: 78; copy number 7: 88; copy number 8: 67; copy number 10: 4; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,590,639–2,633,016, 1 gene (within-gene range 0–1): MMEL1.
- chr18:50,457,887–52,339,025, 22 genes: RPLP0P11, MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.1.
- chr18:52,409,042–52,419,644, 2 genes (within-gene range 0–1): AC011155.1, VN1R76P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 238 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,636,882–45,377,953, 123 genes, copy number 5–10 (within-gene range 1–15) (broad region; genes not listed).
- chr6:47,878,028–48,150,005, 2 genes, copy number 8–15: PTCHD4, HNRNPA3P4.
- chr9:34,810,020–36,677,683, 80 genes, copy number 7 (broad region; genes not listed).
- chr19:37,093,019–37,469,275, 13 genes, copy number 5 (within-gene range 2–5): AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569.
- chr19:39,776,595–40,285,536, 20 genes, copy number 5 (within-gene range 2–5): LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1.

Autosomal genes at a single copy (total copy number 1): 15,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
